Somatic mutation profile of tumor specimen 0DPZTS from CCDI case PBCCVL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 4.7 years (1,720 days).
Specimen 0DPZTS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ef2044d-a0aa-4c2c-a33e-89d47868332e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPZUA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4abfd897-fa0c-4e04-b0e3-7048775e4695

The open-access MAF lists 35 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Intron 4, Frame Shift Del 3, 3'UTR 2, 5'UTR 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.2837T>C p.M946T | Missense Mutation (SNP) | VAF 172/489 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs541218848, COSV52206341; called by muse, mutect2, varscan2
- CARD11 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62716832; called by muse, mutect2, varscan2
- CREB3L3 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.072); catalogued as COSV50173748; called by muse, mutect2, varscan2
- FARP2 | c.1919A>G p.H640R | Missense Mutation (SNP) | VAF 85/341 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs775908482; called by muse, mutect2, varscan2
- HBB | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 78/397 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs33985847, CD073647, CD951729, CM983472; ClinVar: other; called by muse, mutect2, varscan2
- PRR12 | c.988G>T p.G330C (on ENST00000615927; = p.G1151C on NM_020719.3) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101330697; called by muse, mutect2, varscan2
- SEC16A | c.4651G>A p.V1551M | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as rs376298967; called by muse, mutect2, varscan2
- SYNPO2 | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs370448025, COSV61117879; called by muse, mutect2, varscan2
- ADGRF2 | c.788A>G p.Y263C (on ENST00000296862 / NM_001368115.2; = p.Y195C on NM_153839.7) | Missense Mutation (SNP) | VAF 123/427 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALMS1 | c.1099G>C p.V367L | Missense Mutation (SNP) | VAF 126/575 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CIT | c.3047A>G p.K1016R | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DNAH11 | c.7426G>T p.D2476Y | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- GRM5 | c.1325T>A p.M442K | Missense Mutation (SNP) | VAF 121/616 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- LMO7 | c.1267del p.E423Kfs*47 (on ENST00000357063; = p.E153Kfs*47 on NM_015842.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 84/387 reads (22%) | called by mutect2, varscan2
- MBP | c.814C>G p.H272D (on ENST00000355994 / NM_001025101.2; = p.H154D on NM_002385.3) | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); called by muse, mutect2
- PABPC1 | c.1447+2T>G p.X483_splice | Splice Site (SNP) | VAF 94/733 reads (13%) | called by muse, varscan2
- PI3 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 70/344 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); called by muse, varscan2
- PLXNA2 | c.5628del p.Q1877Sfs*45 | Frame Shift Del (DEL) | VAF 116/380 reads (31%) | called by mutect2, varscan2
- PPP1R13L | c.1402G>C p.G468R | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RETREG1 | c.894del p.E300Sfs*54 (on ENST00000306320 / NM_001034850.2; = p.E159Sfs*54 on NM_019000.4) | Frame Shift Del (DEL) | VAF 116/423 reads (27%) | called by mutect2, varscan2
- SEH1L | c.794A>T p.K265M | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ZNF444 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- HMCN1 | c.14943T>C p.D4981= | Silent (SNP) | VAF 158/537 reads (29%) | called by muse, mutect2, varscan2
- MDGA2 | c.2514A>G p.T838= (on ENST00000399232 / NM_001113498.2; = p.T540= on NM_182830.4) | Silent (SNP) | VAF 176/632 reads (28%) | called by muse, mutect2, varscan2
- MEP1A | c.1641G>A p.P547= | Silent (SNP) | VAF 58/237 reads (24%) | catalogued as rs759729059; called by muse, mutect2, varscan2
- PIWIL1 | c.1098C>A p.P366= | Silent (SNP) | VAF 90/398 reads (23%) | called by muse, mutect2, varscan2
- TTN | c.807G>C p.P269= | Silent (SNP) | VAF 65/269 reads (24%) | catalogued as rs779966449; ClinVar: likely benign; called by muse, mutect2, varscan2
- AARD | c.*95T>C | 3'UTR (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2
- DCTN1 | c.3212-14dup | Intron (INS) | VAF 28/120 reads (23%) | catalogued as rs754183694; called by mutect2, varscan2
- DNHD1 | c.11054-15G>T | Intron (SNP) | VAF 49/183 reads (27%) | called by muse, mutect2, varscan2
- HMGN3 | c.-4C>T | 5'UTR (SNP) | VAF 106/349 reads (30%) | called by muse, mutect2, varscan2
- PABPN1L | c.*90G>A | 3'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as rs772823694; called by mutect2, varscan2
- PIH1D1 | chr19:49453448 T>A | 5'Flank (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- PLOD2 | c.109+46G>A | Intron (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- TSPAN16 | c.603+59T>A | Intron (SNP) | VAF 15/65 reads (23%) | called by mutect2, varscan2
